Surgical pathology report (de-identified scan), TCGA case TCGA-IH-A3EA, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Miami, specimen TCGA-IH-A3EA-01A (Primary Tumor).

[page 1 of 3]
Surgical Pathology Report

Name: [REDACTED]
DOB: [REDACTED] (Age [REDACTED])
Gender: M
MRN: [REDACTED]
Location: [REDACTED]
Physician: [REDACTED]

Pathologic Interpretation:

- A. Scalp melanoma single black stitch -anterior, double black stitch-posterior, 1 blue stitch - left, 2 blue stitch-right:
- Ulcerated malignant melanoma, 6.5 cm in greatest dimension, margins free. See tumor summary.
- B. Left occipital sentinel node #1-count # 1
- Connective tissue, no pathologic diagnosis.
- C. Left occipital sentinel node #2-count #
- Connective tissue, no pathologic diagnosis
- D. Left posterior cervical chain sentinel node #1-count #
- One lymph node, no tumor seen (0/1).
- E. Left occipital sentinel node #3-count #
- One lymph node, no tumor seen (0/1).
- F. Left occipital sentinel node #4 - count #
- One lymph node, no tumor seen (0/1).
- G. Left supra clavicular sentinel node count #
- Six lymph nodes, no tumor seen (0/6).
- H. Right posterior cervical sentinel node count #1 #.
- One lymph node, no tumor seen (0/1).
- I. Right posterior cervical sentinel node #2 count #
- One lymph node, no tumor seen (0/1).
- J. Right posterior cervical sentinel node #3 count #
- One lymph node, no tumor seen (0/1).
- K. Right posterior cervical lymph node #4 count #
- Two lymph nodes, no tumor seen.
- L. Right posterior cervical lymph node #5 count #
- One lymph node, no tumor seen (0/1).

ICD-0-3

Melanoma, nodular 8721/3

Site: Skin of head, NOS C44.4

bw 10/26/11

Tumor Summary:

Specimen Type: Excision, wide

Macroscopic Tumor: Present

Tumor Site: Head

Lesion Size

- Greatest dimension: 6.5 cm

- Additional dimensions: 5 x 2.7 cm

Satellite Nodule(s): Absent

Histologic Type: Nodular melanoma

Ulceration: Present

Depth of Invasion: Difficult to determine. No tumor is present in the adipose tissue

Regional Lymph Nodes:

- Number identified: 14

- Number containing metastases identified macroscopically: 0

- Number containing metastases identified microscopically: 0

[page 2 of 3]
[REDACTED]

Lateral Margins: Uninvolved by invasive melanoma
Deep Margin: Uninvolved by invasive melanoma

Pathologic Staging (pTNM): T4b, N0, MX

NOTE: Some immunohistochemical antibodies are analyte specific reagents (ASRs) validated by our laboratory. These ASRs are clinically useful indicators that do not require FDA approval. These clones are used: IDS-ER, PgR 636-PR, A485-HER2, H-11-EGFR. All immunohistochemical stains are used with formalin or molecular fixed, paraffin embedded tissue. Detection is by a colorimetric method. Results are read by a pathologist as positive or negative.

As the attending pathologist, I attest that I: (i) Examined the relevant preparation(s) for the specimen(s); and (ii) Rendered the diagnosis(es).

[REDACTED]

Procedures/Addenda
Addendum

Addendum Diagnosis

ADDENDUM:

- Immunostains for S-100 and HMB45 were performed on the lymph nodes in specimens D, E, F, G, H, I, J, K and L. None of them show evidence of metastatic melanoma.

[REDACTED]

Addendum

Addendum Diagnosis

Addendum (A):

- Tumor thickness is at least 1.5 cm.
- True thickness cannot be determined due to ulceration.

[REDACTED]

Clinical History:

None provided

Operation Performed

Wide excision of melanoma in head

Pre Operative Diagnosis:

[REDACTED]

[page 3 of 3]
Melanoma of the head

Specimen(s) Received:

- A: Scalp melanoma single black stitch -anterior, double black stitch-posterior, 1 blue stitch - left, 2 blue stitch-right
B: Left occipital sentinel node #1-count #
C: Left occipital sentinel node #2-count #
D: Left posterior cervical chain sentinel node #1-count #
E: Left occipital sentinel node #3-count #
F: Left occipital sentinel node #4 - count #
G: Left supra clavicular sentinel node count #
H: Right posterior cervical sentinel node count #1 #
I: Right posterior cervical sentinel node #2 count#
J: Right posterior cervical sentinel node #3 count #
K: Right posterior cervical lymph node #4 count #
L: Right posterior cervical lymph node #5 count #

Gross Description:

- A. Received fresh is a round excision of skin with a large brown indurated mass. The entire specimen measures, 9.5 x 7.5 x 3.5 cm. The large round mass measures, 6.5 x 5.0 x 2.7 cm. The specimen is oriented with one single black stitch anterior, one double black stitch posterior, one blue stitch left and two blue stitches right. The specimen is inked for oriented for orientation purposes as follows; anterior inked red, posterior orange, left is blue and deep margin is inked in black. Cut sections of the specimen reveals that the lesion does not penetrate into the deep margin. The deep margin being the closest margin, approximately less than 0.3 cm from the deep margin.
- 1 Deep margin
- 2 Anterior
- 3 Posterior
- 4 Yellow
- 5 Blue
- 6-11 Representative section of lesion
- B. Received in molecular fixative is less than 0.5 cm pale-tan soft tissue fragment. Submitted in toto in one cassette.
- C. Received in molecular fixative is less than 0.5 cm pale-tan soft tissue fragment. Submitted in toto in one cassette.
- D. Received in molecular fixative is a pale-tan soft tissue fragment measuring less than 0.5 cm in greatest dimension. Submitted in toto in one cassette.
- E. Received in molecular fixative is a pale-tan soft tissue fragment measuring less than 0.5 cm in greatest dimension. Submitted in toto in one cassette.
- F. Received in molecular fixative is a pale-tan soft tissue fragment measuring less than 0.5 cm in greatest dimension. Submitted in toto in one cassette.
- G. Received in molecular fixative is a 1.7 cm pale-tan soft tissue fragment. Bisected and submitted in toto in two cassettes. Two possible lymph nodes
- H. Received in molecular fixative is a pale-tan soft tissue fragment measuring less than 0.5 cm in greatest dimension. Submitted in toto in one cassette.
- I. Received in molecular fixative pale-tan soft tissue fragment measuring less than 0.5 cm in greatest dimension. Submitted in toto in one cassette.
- J. Received in molecular fixative pale-tan soft tissue fragment measuring less than 0.5 cm in greatest dimension. Submitted in toto in one cassette.
- K. Received in molecular fixative is a 1.2 cm pale-tan soft tissue fragment. Bisected and submitted in toto in two cassettes.
- L. Received in molecular fixative is a pale-tan soft tissue fragment measuring less than 0.5 cm in greatest dimension. Submitted in toto in one cassette.

Source: NCI Genomic Data Commons file f8418fa3-3302-4fc8-84fc-ebedc47457d7 (TCGA-IH-A3EA.EA214BC5-6B10-41AF-B29A-3D52EDA21CCC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).